Somatic mutation profile of tumor specimen 0E1KOJ from CCDI case PBCWGL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1KOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e404fd8d-564c-4d10-bf7c-e6dcb08f1160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1KO5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/179d016c-9fa6-4d53-83b7-b0b32aabc805

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARNT | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 56/350 reads (16%) | catalogued as COSV104416815; called by muse, varscan2
- BCL6B | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.474); catalogued as rs1311866828; called by muse, varscan2
- CHST6 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 91/168 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1312118035; called by muse, varscan2
- DLL1 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs41269633; called by muse, varscan2
- TMTC4 | c.1229C>A p.A410E (on ENST00000376234 / NM_001350577.2; = p.A429E on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/564 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100168855; called by muse, varscan2
- RHPN1 | c.1786C>A p.L596M | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.443); called by muse, varscan2
- ZNF669 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 75/671 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.986); called by muse, varscan2
- ABTB2 | c.1500G>A p.T500= | Silent (SNP) | VAF 62/225 reads (28%) | catalogued as rs749917908; called by muse, varscan2
- HYAL4 | c.1314T>C p.Y438= | Silent (SNP) | VAF 52/370 reads (14%) | called by muse, varscan2
- MNX1 | c.447C>A p.G149= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, varscan2
- UNC13C | c.2418A>G p.S806= | Silent (SNP) | VAF 96/188 reads (51%) | called by muse, varscan2
- BLNK | c.677-36G>T | Intron (SNP) | VAF 12/82 reads (15%) | called by muse, varscan2
